Somatic mutation profile of tumor specimen CDDP-ACQQ-TTP1-A (aliquot CDDP-ACQQ-TTP1-A-2-0-D-A572-36) from CDDP_EAGLE case CDDP-ACQQ, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63 years.
Specimen CDDP-ACQQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e17e81a-a165-4f42-91d9-9e86dd83eb5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACQQ-NB1-A (Blood Derived Normal), aliquot CDDP-ACQQ-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eec1f17-fa41-4025-a36f-0db337b990bf

The open-access MAF lists 994 somatic variants for this specimen: 636 protein-altering or splice-affecting, 232 silent, 126 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 549, Silent 232, Intron 60, Nonsense Mutation 48, RNA 22, Frame Shift Del 16, 3'UTR 14, 5'UTR 13, 5'Flank 13, Splice Site 10, Splice Region 7, Frame Shift Ins 5.

Variants (750 of 994; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2702T>C p.I901T | Missense Mutation (SNP) | VAF 58/684 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1305120399, COSV55952788; called by muse, mutect2
- ABCB11 | c.1556G>T p.G519V | Missense Mutation (SNP) | VAF 52/420 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV55585698; called by muse, mutect2, varscan2
- ABCF3 | c.1304A>G p.Q435R | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.222); catalogued as rs1417065045; called by muse, mutect2, varscan2
- ACP4 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54516228; called by muse, mutect2, varscan2
- ACTG2 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); catalogued as COSV61829846; called by muse, mutect2
- ACTN3 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV72207521; called by muse, mutect2, varscan2
- ADGRG5 | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs937583855, COSV100446510; called by muse, mutect2, varscan2
- ADGRL2 | c.1996G>T p.E666* (on ENST00000370717 / NM_001366005.1; = p.E653* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV54665268; called by muse, varscan2
- AHNAK | c.6587C>T p.P2196L | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1226119522; called by muse, mutect2, varscan2
- AKAP7 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV63505492; called by muse, mutect2, varscan2
- AKTIP | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as COSV55815478; called by muse, mutect2, varscan2
- ANKRD34C | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1490294400; called by muse, mutect2, varscan2
- ANO2 | c.712C>G p.P238A (on ENST00000356134 / NM_001278597.3; = p.P242A on NM_001278596.3) | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV59024211; called by muse, varscan2
- AR | c.2339G>T p.R780L | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV65954336; called by muse, mutect2
- ARID5B | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs753241704; called by muse, mutect2, varscan2
- ARMC4 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 68/402 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59457397, COSV59465859; called by muse, mutect2, varscan2
- ASPN | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs1040181197; called by muse, mutect2, varscan2
- ASTL | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151115044; called by mutect2, varscan2
- ATR | c.4504-1G>C p.X1502_splice | Splice Site (SNP) | VAF 34/346 reads (10%) | catalogued as rs910635641, COSV63395111; called by muse, mutect2
- BBS12 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as rs1317012035; called by muse, mutect2, varscan2
- BCAP29 | c.345-1G>C p.X115_splice | Splice Site (SNP) | VAF 38/382 reads (10%) | catalogued as COSV50051692; called by muse, mutect2
- BCL9 | c.4203G>T p.R1401S | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99324345; called by muse, mutect2, varscan2
- BCR | c.3488G>A p.C1163Y | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs1264023995; called by muse, mutect2, varscan2
- BNC1 | c.2759C>A p.A920D | Missense Mutation (SNP) | VAF 130/371 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV100597545; called by muse, mutect2, varscan2
- BRINP3 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 55/243 reads (23%) | catalogued as rs865971143; called by muse, mutect2, varscan2
- BRMS1L | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV99396539; called by muse, mutect2, varscan2
- BTBD8 | c.2459G>T p.S820I (on ENST00000636805 / NM_001376131.1; = p.S307I on NM_015237.4) | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV64883532; called by muse, mutect2, varscan2
- BTN2A2 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 83/431 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100760430; called by muse, mutect2, varscan2
- C10orf71 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as rs1011129764; called by muse, mutect2, varscan2
- C10orf82 | c.224T>A p.V75D | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781819680; called by muse, mutect2, varscan2
- C3orf38 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs768547184; called by muse, varscan2
- C5orf52 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV69625748; called by muse, varscan2
- C6 | c.2609G>A p.W870* | Nonsense Mutation (SNP) | VAF 42/509 reads (8%) | catalogued as COSV99666679; called by muse, mutect2
- CA5A | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59242160; called by muse, mutect2, varscan2
- CABS1 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 89/310 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1173109705; called by muse, mutect2, varscan2
- CCDC170 | c.85C>G p.P29A | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV53340640; called by muse, mutect2, varscan2
- CDC23 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs746374234; called by mutect2, varscan2
- CDH10 | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs963500072, COSV52569089; called by muse, mutect2
- CDH9 | c.2197G>C p.D733H | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50258336; called by muse, mutect2
- CDRT4 | c.306G>T p.W102C | Missense Mutation (SNP) | VAF 51/453 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1445502622; called by muse, mutect2, varscan2
- CEACAM20 | c.1678C>A p.L560M | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV57601173; called by muse, mutect2, varscan2
- CELSR1 | c.4540G>A p.V1514M | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754974275, COSV99418565; called by muse, varscan2
- CFAP47 | c.1526T>C p.F509S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52885057; called by muse, mutect2, varscan2
- CHSY3 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1033562678, COSV59275201; called by muse, varscan2
- CLUH | c.3574G>C p.E1192Q (on ENST00000435359; = p.E1231Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs769367557; called by muse, mutect2, varscan2
- CNTN3 | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs375992095; called by muse, mutect2, varscan2
- CR2 | c.640C>G p.R214G | Missense Mutation (SNP) | VAF 94/648 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100889578; called by muse, mutect2, varscan2
- CRBN | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 67/377 reads (18%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs752968990; called by muse, mutect2, varscan2
- CRTC1 | c.535A>G p.R179G | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs749820215; called by muse, mutect2, varscan2
- CST2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768529969; called by muse, mutect2, varscan2
- CUX1 | c.1114G>T p.A372S (on ENST00000292535 / NM_181552.4; = p.A383S on NM_001913.5) | Missense Mutation (SNP) | VAF 48/498 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52897791; called by muse, mutect2
- CUX1 | c.1557C>T p.A519= (on ENST00000437600 / NM_181500.4; = p.A521= on NM_001913.5) | Splice Region (SNP) | VAF 16/115 reads (14%) | catalogued as rs199822336; called by muse, mutect2, varscan2
- DNAH11 | c.5027C>A p.A1676E | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs776072985; called by muse, mutect2, varscan2
- DNER | c.1997G>C p.R666P | Missense Mutation (SNP) | VAF 71/550 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59160945, COSV59173630; called by muse, mutect2, varscan2
- DOCK4 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70315776; called by muse, mutect2, varscan2
- DPYSL5 | c.971C>A p.S324* | Nonsense Mutation (SNP) | VAF 39/300 reads (13%) | catalogued as COSV99982637; called by muse, mutect2, varscan2
- DRD3 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.127); catalogued as rs867863807; called by muse, mutect2, varscan2
- ECHS1 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV63907558; called by muse, mutect2, varscan2
- EPPK1 | c.4862G>A p.R1621Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs782353672, COSV73260891; called by muse, mutect2, varscan2
- FAM135B | c.229del p.R77Gfs*7 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | catalogued as COSV104372835; called by mutect2, pindel, varscan2
- FAM227A | c.628A>T p.K210* | Nonsense Mutation (SNP) | VAF 50/176 reads (28%) | catalogued as rs777640180; called by muse, mutect2, varscan2
- FAM76A | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV50550171; called by muse, mutect2
- FANCA | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 83/548 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66883582; called by muse, mutect2, varscan2
- FBLN5 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 90/612 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs759434738, COSV99969745; called by muse, mutect2, varscan2
- FBXL7 | c.996C>A p.S332R | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV61648068; called by muse, mutect2
- FBXO41 | c.2198G>A p.R733H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs765916084; called by mutect2, varscan2
- FGA | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 61/438 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs184672247; called by muse, mutect2, varscan2
- FMR1NB | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 32/387 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV100789520; called by muse, mutect2
- FPGT-TNNI3K | c.836C>A p.A279E | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.844); catalogued as rs764371387; called by muse, mutect2, varscan2
- FZD9 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.049); catalogued as rs1554563309; called by muse, mutect2, varscan2
- GABRA2 | c.855T>C p.F285= | Splice Region (SNP) | VAF 52/449 reads (12%) | catalogued as COSV62918697; called by muse, mutect2, varscan2
- GALNT17 | c.1669-1G>A p.X557_splice | Splice Site (SNP) | VAF 36/642 reads (6%) | catalogued as COSV61168513; called by muse, mutect2
- GARNL3 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59223838; called by muse, mutect2, varscan2
- GATC | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.207); catalogued as rs1449619966; called by mutect2, varscan2
- GFRA1 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as rs1298958711; called by muse, mutect2, varscan2
- GLP2R | c.926C>A p.A309D | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52325275; called by muse, mutect2
- GPR4 | c.40C>A p.R14S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV59916145; called by muse, mutect2, varscan2
- GRK1 | c.1541G>T p.C514F | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as CM962583; called by muse, mutect2, varscan2
- H3C2 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV52519139; called by muse, mutect2, varscan2
- HFM1 | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as COSV99646455; called by muse, mutect2, varscan2
- HIPK4 | c.1144C>A p.P382T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99396315; called by muse, mutect2, varscan2
- HORMAD1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs1214536879, COSV59270290; called by muse, mutect2
- ILF3 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV51560759; called by muse, mutect2, varscan2
- INF2 | c.2788C>T p.R930W | Missense Mutation (SNP) | VAF 104/544 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs764687744; called by muse, mutect2, varscan2
- INPP4A | c.2378G>A p.R793Q (on ENST00000074304 / NM_001134224.1; = p.R754Q on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs1231375445, COSV50789712; called by muse, mutect2, varscan2
- IRAG2 | c.4196C>G p.S1399C (on ENST00000636465; = p.S444C on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57231091; called by muse, mutect2, varscan2
- IRGQ | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV60670983, COSV60671165; called by muse, mutect2, varscan2
- IRS1 | c.2426C>G p.S809C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as CM963061; called by mutect2, varscan2
- ITIH1 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768299617; called by muse, varscan2
- KBTBD3 | c.1807A>T p.R603* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV101595688; called by mutect2, varscan2
- KCNAB2 | c.765C>A p.Y255* | Nonsense Mutation (SNP) | VAF 72/331 reads (22%) | catalogued as COSV51236953; called by muse, mutect2, varscan2
- KCNB2 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.03); catalogued as COSV73052834; called by muse, mutect2, varscan2
- KCNJ2 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 109/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54661859; called by muse, mutect2, varscan2
- KDM5B | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 39/212 reads (18%) | catalogued as COSV99351436; called by muse, mutect2, varscan2
- KEAP1 | c.1252_1253insC p.V418Afs*27 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | catalogued as COSV50665539; called by mutect2, pindel, varscan2
- KIF3B | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); catalogued as COSV65228590; called by muse, mutect2, varscan2
- KRTAP27-1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 62/365 reads (17%) | catalogued as COSV67001359; called by muse, mutect2, varscan2
- L3MBTL1 | c.337C>T p.P113S (on ENST00000418998 / NM_001377303.1; = p.P91S on NM_032107.5) | Missense Mutation (SNP) | VAF 61/290 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV100917113; called by muse, mutect2, varscan2
- LILRA4 | c.926G>A p.S309N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52494900; called by muse, mutect2, varscan2
- LMAN1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs1294142528; called by muse, mutect2, varscan2
- LOXHD1 | c.4417G>T p.G1473W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1418720406; called by muse, mutect2, varscan2
- LRFN5 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 60/368 reads (16%) | catalogued as COSV53243425; called by muse, mutect2, varscan2
- LRRC61 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs756782781; called by muse, mutect2, varscan2
- LUM | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287499025; called by muse, mutect2, varscan2
- MAGEA4 | c.522C>G p.S174R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as COSV99367296; called by muse, mutect2, varscan2
- MAP3K19 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.269); catalogued as rs1457326347; called by muse, mutect2, varscan2
- MED16 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 58/297 reads (20%) | catalogued as rs1323150118; called by muse, mutect2, varscan2
- MEFV | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs757216434, COSV54819090, COSV54827097, COSV99560859; called by mutect2, varscan2
- MGAM2 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198193989; called by muse, varscan2
- MICAL2 | c.2423G>A p.R808K | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV56325622; called by muse, mutect2, varscan2
- MROH2B | c.3938G>C p.W1313S | Missense Mutation (SNP) | VAF 67/355 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.104); catalogued as COSV101270452; called by muse, mutect2, varscan2
- MROH5 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101436009; called by muse, varscan2
- MROH9 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100883106; called by muse, mutect2, varscan2
- MSH3 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 22/217 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.422); catalogued as rs1276965330; called by muse, mutect2, varscan2
- MTMR8 | c.1524G>T p.Q508H | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66392242; called by muse, mutect2
- MUSK | c.1659G>A p.M553I | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1430558547; called by muse, mutect2, varscan2
- MYH1 | c.1858C>A p.L620M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV56849580; called by muse, varscan2
- MYH14 | c.2329C>T p.L777F | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99221376; called by muse, mutect2, varscan2
- MYT1L | c.1522G>C p.G508R | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67706764; called by muse, mutect2, varscan2
- NEK5 | c.1609A>G p.M537V | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1486396901; called by muse, mutect2
- NF1 | c.7113C>A p.C2371* (on ENST00000358273 / NM_001042492.3; = p.C2350* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 113/322 reads (35%) | catalogued as CM1414935; called by muse, mutect2, varscan2
- NFASC | c.113C>T p.T38M (on ENST00000339876 / NM_001378329.1; = p.T32M on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs564513596; called by muse, mutect2, varscan2
- NIN | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55405250; called by muse, varscan2
- NPR1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV64140283; called by muse, mutect2, varscan2
- NUP85 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs753666447; called by muse, mutect2, varscan2
- NYNRIN | c.1197del p.I400Ffs*3 | Frame Shift Del (DEL) | VAF 18/167 reads (11%) | catalogued as rs1200627965, COSV66842471; called by mutect2, pindel, varscan2
- OR11L1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs756293820; called by muse, varscan2
- OR1S1 | c.67A>C p.T23P | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs185034442; called by muse, mutect2, varscan2
- OR2T6 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV63215631; called by muse, mutect2, varscan2
- OR5D16 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101003889; called by muse, mutect2, varscan2
- OR6C4 | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV67793301; called by muse, mutect2, varscan2
- PCDHB8 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 38/620 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as rs1439209426, COSV50753598; called by muse, mutect2
- PDILT | c.1274C>T p.P425L | Missense Mutation (SNP) | VAF 51/271 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100199008; called by muse, mutect2, varscan2
- PDLIM5 | c.1240G>C p.G414R | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100524594; called by muse, mutect2, varscan2
- PDZRN4 | c.2227G>A p.E743K (on ENST00000402685 / NM_001164595.2; = p.E485K on NM_013377.4) | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54192285, COSV54198313; called by muse, mutect2, varscan2
- PHACTR1 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60678972; called by muse, mutect2, varscan2
- PHF23 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.27); catalogued as COSV99138342; called by muse, mutect2
- PIEZO2 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs557549695; called by muse, mutect2, varscan2
- PKD1 | c.9830G>A p.R3277H | Missense Mutation (SNP) | VAF 232/804 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238446180; called by muse, mutect2, varscan2
- PKD1 | c.2197C>G p.P733A | Missense Mutation (SNP) | VAF 96/450 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.114); catalogued as COSV99237929; called by mutect2, varscan2
- PKHD1 | c.5166C>G p.I1722M | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV61863471; called by muse, mutect2
- PLXNA4 | c.4537C>T p.P1513S | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV58146719; called by muse, mutect2
- PPP1R18 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as COSV51299292; called by muse, mutect2, varscan2
- PPP2R5E | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61744757; called by muse, mutect2, varscan2
- PRRC2A | c.3238del p.R1080Efs*130 | Frame Shift Del (DEL) | VAF 23/158 reads (15%) | catalogued as COSV65686419; called by mutect2, pindel, varscan2
- PTPN18 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as rs766772512, COSV99447591; called by mutect2, varscan2
- PXMP2 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs778533797; called by muse, mutect2
- RAD51AP2 | c.3325G>A p.G1109R | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1363383167, COSV67587293, COSV67589170, COSV67589555; called by muse, mutect2, varscan2
- RASA1 | c.2284C>T p.H762Y | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as rs1028615902; called by mutect2, varscan2
- RCC2 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 129/406 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100965135; called by muse, mutect2, varscan2
- RGS13 | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV67345944; called by muse, mutect2, varscan2
- RGS9 | c.1563C>G p.I521M | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); catalogued as COSV52223178; called by muse, mutect2
- RPRM | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1196453867, COSV57988436; called by muse, mutect2, varscan2
- RUBCN | c.2818G>T p.E940* | Nonsense Mutation (SNP) | VAF 16/165 reads (10%) | catalogued as COSV99584863; called by muse, mutect2, varscan2
- RYR1 | c.2048T>A p.V683E | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62112489; called by muse, mutect2, varscan2
- SCN5A | c.4919C>G p.A1640G (on ENST00000333535 / NM_198056.3; = p.A1639G on NM_000335.5) | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61125720; called by muse, mutect2, varscan2
- SEC14L3 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53179872; called by muse, mutect2, varscan2
- SEMA6A | c.2171C>A p.T724K | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs769576529, COSV56711314; called by muse, mutect2, varscan2
- SETBP1 | c.3285C>A p.F1095L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99952502; called by muse, mutect2, varscan2
- SGO1 | c.1470T>A p.A490= (on ENST00000263753 / NM_001012410.5; = p.A221= on NM_138484.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/40 reads (20%) | catalogued as rs1401823139; called by muse, mutect2, varscan2
- SHB | c.1314del p.T439Pfs*10 | Frame Shift Del (DEL) | VAF 35/214 reads (16%) | catalogued as COSV66630016; called by mutect2, pindel, varscan2
- SLC45A3 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs760168590, COSV65655235; called by muse, mutect2, varscan2
- SLCO1B1 | c.1655G>A p.G552D | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as rs747091904; called by muse, mutect2, varscan2
- SMARCA2 | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 119/535 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.448); catalogued as rs1158247037; called by muse, mutect2, varscan2
- SMTNL2 | c.399+2T>G p.X133_splice | Splice Site (SNP) | VAF 16/98 reads (16%) | catalogued as rs1300242903; called by muse, mutect2, varscan2
- SORCS3 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 88/353 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63829105; called by muse, mutect2, varscan2
- SPG7 | c.767A>T p.Y256F | Missense Mutation (SNP) | VAF 58/426 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.112); catalogued as rs773926412; called by muse, mutect2, varscan2
- SRD5A3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs745955548; called by muse, mutect2
- SRGAP1 | c.1415G>C p.R472T | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs368521108, COSV61894272; called by muse, mutect2, varscan2
- SRSF6 | c.974G>C p.R325T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); catalogued as rs770725827; called by mutect2, varscan2
- STON2 | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 50/400 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV50843339; called by muse, mutect2, varscan2
- STRIP2 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148770152; called by mutect2, varscan2
- SWT1 | c.682A>G p.R228G | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs774649811; called by muse, mutect2, varscan2
- SYCP1 | c.1022T>C p.L341S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1193723934; called by mutect2, varscan2
- TAS2R60 | c.662del p.G221Efs*23 | Frame Shift Del (DEL) | VAF 40/295 reads (14%) | catalogued as COSV60330726; called by mutect2, pindel, varscan2
- TCEAL2 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 25/341 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs1056913574; called by muse, mutect2
- TENM3 | c.6368C>A p.A2123D | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV69305080; called by muse, mutect2, varscan2
- TLE2 | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs1198926960; called by muse, mutect2, varscan2
- TLR2 | c.961A>G p.R321G | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV52605420; called by muse, mutect2
- TMPRSS15 | c.31C>A p.H11N | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV53035608; called by muse, mutect2, varscan2
- TMPRSS6 | c.896T>C p.M299T | Missense Mutation (SNP) | VAF 61/390 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1230321237; called by muse, mutect2, varscan2
- TNS1 | c.3092G>T p.R1031L | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99409961; called by muse, mutect2, varscan2
- TP53 | c.466del p.R156Afs*14 | Frame Shift Del (DEL) | VAF 64/209 reads (31%) | catalogued as CD156964, COSV52711846, COSV52730924, COSV53119766; called by mutect2, pindel, varscan2
- TRADD | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs763349245, COSV61460081; called by muse, mutect2, varscan2
- TRAV10 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs866953660; called by muse, mutect2, varscan2
- TRDMT1 | c.402A>G p.I134M | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs763830612; called by muse, mutect2, varscan2
- TRIM14 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1375683603, COSV52965087; called by muse, mutect2
- TRIM51GP | c.183G>C p.Q61H | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs768755358; called by muse, varscan2
- TRMT9B | c.818A>T p.N273I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV71600252; called by mutect2, varscan2
- TRMU | c.980T>A p.M327K | Missense Mutation (SNP) | VAF 94/328 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs770559905; called by muse, mutect2, varscan2
- TTN | c.53734C>T p.R17912W (on ENST00000591111; = p.R10488W on NM_003319.4) | Missense Mutation (SNP) | VAF 49/364 reads (13%) | PolyPhen probably damaging (0.917); catalogued as rs372959465, COSV59884908, COSV60001200; called by muse, mutect2, varscan2
- TTN | c.18079G>A p.D6027N (on ENST00000591111; = p.D5100N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/176 reads (8%) | PolyPhen benign (0); catalogued as rs794729617; ClinVar: uncertain significance; called by muse, mutect2
- UGGT1 | c.2993G>A p.R998K | Missense Mutation (SNP) | VAF 46/455 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs867014617; called by muse, mutect2, varscan2
- UNCX | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 163/807 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1311867015; called by muse, mutect2, varscan2
- VCL | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 66/492 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV53008608; called by muse, mutect2, varscan2
- WDR20 | c.1123G>A p.D375N | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54475189; called by muse, mutect2, varscan2
- WDR90 | c.2274C>A p.F758L | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.082); catalogued as COSV99553311; called by muse, mutect2, varscan2
- WRAP53 | c.1241A>G p.N414S | Missense Mutation (SNP) | VAF 194/522 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs543868835; called by muse, mutect2, varscan2
- ZDBF2 | c.5675C>A p.A1892D | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV65622438; called by muse, mutect2, varscan2
- ZDHHC18 | c.1060C>G p.R354G | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65145806; called by muse, varscan2
- ZFHX4 | c.3331G>T p.A1111S | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.099); catalogued as COSV99257417; called by muse, mutect2, varscan2
- ZNF124 | c.930G>T p.R310S (on ENST00000543802 / NM_001297568.1; = p.R248S on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100517813; called by muse, mutect2, varscan2
- ZNF324B | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV60742154; called by muse, mutect2, varscan2
- ZNF420 | c.854G>T p.R285M | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58495680; called by muse, mutect2, varscan2
- ZNF518B | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as rs775287668; called by muse, mutect2, varscan2
- ZNF667 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs202093161, COSV52630823, COSV52631642; called by muse, mutect2, varscan2
- ZNF782 | c.2060C>G p.S687* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV56650950; called by muse, mutect2, varscan2
- ZNHIT2 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs559096123; called by mutect2, varscan2
- ZSCAN21 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as COSV52850590; called by muse, mutect2, varscan2
- ZYX | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs756942984; called by muse, mutect2, varscan2
- ABCB4 | c.2527G>T p.G843* | Nonsense Mutation (SNP) | VAF 28/512 reads (5%) | called by muse, mutect2
- ABRAXAS1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- AC100868.1 | c.1498_1503del p.C500_D501del | In Frame Del (DEL) | VAF 6/61 reads (10%) | called by mutect2*, pindel
- ACKR2 | c.677T>C p.M226T | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAMTS12 | c.4355G>T p.G1452V | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); called by muse, mutect2
- ADAMTS12 | c.1642T>G p.W548G | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- ADAMTS17 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 147/412 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ADAMTS3 | c.1091C>A p.A364D | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, varscan2
- ADCY2 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, varscan2
- ADCY2 | c.3128C>A p.T1043N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRE5 | c.1523G>T p.W508L (on ENST00000242786 / NM_078481.4; = p.W415L on NM_001784.5) | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFF1 | c.2902A>T p.M968L | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- AGBL1 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AGXT2 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 30/397 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); called by muse, mutect2
- AJUBA | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- AL031777.2 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); called by muse, mutect2
- ALDH1L1 | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3335G>A p.G1112E | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- ANKRD20A4P | c.2372A>G p.H791R | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ANKRD35 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 58/405 reads (14%) | called by muse, mutect2, varscan2
- ANKS3 | c.661A>G p.M221V | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- APPL1 | c.440A>T p.Y147F | Missense Mutation (SNP) | VAF 32/241 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ARHGAP27 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- ARX | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 90/468 reads (19%) | called by muse, mutect2, varscan2
- ASCC3 | c.3809G>T p.R1270L | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATF7IP2 | c.727A>C p.N243H | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- ATP1A4 | c.341C>A p.T114N | Missense Mutation (SNP) | VAF 53/434 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- ATP6V1G2 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATPAF2 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATR | c.4504G>T p.V1502F | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- AUTS2 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- AVPR1B | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- B4GALNT4 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BBS9 | c.660G>C p.Q220H | Missense Mutation (SNP) | VAF 29/434 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- BEX3 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 37/312 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BNC1 | c.282C>A p.S94R | Missense Mutation (SNP) | VAF 149/395 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BOP1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- BTNL9 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 39/392 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C11orf87 | c.342del p.L115Cfs*162 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | called by mutect2, pindel, varscan2
- C19orf47 | c.429C>G p.I143M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- C5AR1 | c.690G>C p.W230C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- C7 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 63/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CA4 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1I | c.263T>A p.V88E | Missense Mutation (SNP) | VAF 39/323 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALCA | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- CALR3 | c.830A>C p.H277P | Missense Mutation (SNP) | VAF 69/502 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CATSPERD | c.1808T>A p.V603E | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC39 | c.302T>G p.I101S | Missense Mutation (SNP) | VAF 31/384 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.153); called by muse, mutect2
- CCDC57 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC92 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNA1 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 85/330 reads (26%) | called by muse, mutect2, varscan2
- CDC42BPG | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH9 | c.2079G>C p.M693I | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- CDR2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 136/463 reads (29%) | called by muse, mutect2, varscan2
- CECR2 | c.1455G>C p.E485D (on ENST00000342247 / NM_001290047.2; = p.E302D on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- CELSR1 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CEP162 | c.720dup p.V241Cfs*4 | Frame Shift Ins (INS) | VAF 15/140 reads (11%) | called by mutect2, pindel
- CEP250 | c.1339C>G p.L447V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CFAP44 | c.3509A>G p.Y1170C | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP61 | c.2633A>G p.N878S | Missense Mutation (SNP) | VAF 53/407 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- CHD6 | c.6544G>T p.E2182* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- CHRNA4 | c.860T>C p.V287A | Missense Mutation (SNP) | VAF 75/558 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHST1 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CHST2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHST2 | c.799T>A p.Y267N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CKAP5 | c.4286C>T p.A1429V | Missense Mutation (SNP) | VAF 79/307 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLDN11 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC10A | c.674A>T p.Q225L (on ENST00000254868 / NM_182906.4; = p.Q201L on NM_006344.4) | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CNGA2 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN2 | c.451del p.V151* | Frame Shift Del (DEL) | VAF 46/172 reads (27%) | called by mutect2, pindel, varscan2
- CNTN2 | c.1441T>A p.S481T | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- CNTNAP2 | c.1601A>G p.Y534C | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2
- CNTNAP2 | c.2597C>A p.P866Q | Missense Mutation (SNP) | VAF 128/503 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- COL25A1 | c.1354G>C p.G452R | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A6 | c.3856T>A p.S1286T | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- COL6A2 | c.1180-1G>T p.X394_splice | Splice Site (SNP) | VAF 40/290 reads (14%) | called by muse, mutect2, varscan2
- COL9A3 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CORO1A | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CPS1 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CREBBP | c.7249A>G p.R2417G | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CSAG3 | c.203T>C p.M68T | Missense Mutation (SNP) | VAF 58/1216 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); called by muse, mutect2
- CSMD1 | c.9635C>A p.P3212H (on ENST00000520002; = p.P3211H on NM_033225.6) | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTAGE6 | c.1058C>A p.T353K | Missense Mutation (SNP) | VAF 82/505 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.105); called by muse, varscan2
- CYP2S1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CYP3A7 | c.670+5G>T | Splice Region (SNP) | VAF 32/291 reads (11%) | called by muse, mutect2, varscan2
- DACH1 | c.1211T>A p.M404K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF16 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 39/369 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- DCC | c.1783A>T p.S595C | Missense Mutation (SNP) | VAF 52/337 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- DCHS1 | c.2024T>C p.L675P | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- DDX5 | c.1097G>T p.W366L | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- DENND11 | c.1361G>T p.C454F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- DHX15 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 49/304 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- DHX30 | c.239A>T p.N80I (on ENST00000445061 / NM_138615.3; = p.N41I on NM_014966.3) | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- DISP1 | c.2312T>C p.L771P | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- DLGAP5 | c.1273C>G p.Q425E | Missense Mutation (SNP) | VAF 60/331 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DMD | c.2817G>T p.L939F | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DMXL1 | c.2113C>T p.L705F | Missense Mutation (SNP) | VAF 48/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNM1 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- DNPH1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.096); called by muse, mutect2
- DOCK5 | c.4278G>C p.M1426I | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DPP10 | c.1045T>A p.C349S | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPY30 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.203); called by muse, mutect2
- DPYSL2 | c.916C>A p.P306T | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DRAXIN | c.312_322del p.L105Qfs*87 | Frame Shift Del (DEL) | VAF 28/124 reads (23%) | called by mutect2, varscan2
- DUOX1 | c.2051A>G p.Q684R | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBNA1BP2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 103/381 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ECHDC2 | c.121+8T>C | Splice Region (SNP) | VAF 46/135 reads (34%) | called by muse, mutect2, varscan2
- EHHADH | c.1876T>A p.S626T | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EIF3I | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 32/272 reads (12%) | called by muse, varscan2
- EPB41L5 | c.1905G>T p.L635F | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EPHB6 | c.907del p.Q303Sfs*139 | Frame Shift Del (DEL) | VAF 26/162 reads (16%) | called by mutect2, pindel, varscan2
- EPS15 | c.1537A>T p.S513C | Missense Mutation (SNP) | VAF 91/325 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ERCC4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ERV3-1 | c.1122G>T p.K374N | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2
- ERVV-2 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ETNK2 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 83/475 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXD1 | c.1400C>G p.S467* | Nonsense Mutation (SNP) | VAF 42/280 reads (15%) | called by muse, mutect2, varscan2
- EXOC3 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.202); called by muse, varscan2
- FAH | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 134/405 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- FAM135A | c.1152C>G p.F384L (on ENST00000370479 / NM_001351599.1; = p.F367L on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- FAM91A1 | c.831del p.I277Mfs*25 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- FBN2 | c.4502G>T p.C1501F | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBN3 | c.6810C>A p.N2270K | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- FBXO3 | c.145C>G p.H49D | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- FBXO40 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- FCRL5 | c.2213G>A p.S738N | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FECH | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 63/395 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- FERD3L | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.255); called by muse, mutect2
- FGF8 | c.321G>T p.E107D (on ENST00000344255 / NM_033164.4; = p.E89D on NM_006119.6) | Missense Mutation (SNP) | VAF 152/529 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FIBP | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- FLG | c.5188G>A p.D1730N | Missense Mutation (SNP) | VAF 119/573 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FLNC | c.7048G>A p.A2350T | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FLRT2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- FMR1 | c.1032G>T p.R344S | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.057); called by muse, mutect2
- FOXF1 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- FOXL2NB | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); called by muse, mutect2
- FOXO1 | c.527C>G p.S176W | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.17180A>T p.Q5727L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- FSIP2 | c.17948T>C p.V5983A | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GABRG1 | c.1339T>C p.F447L | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GCC1 | c.1159G>C p.D387H | Missense Mutation (SNP) | VAF 22/433 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GCSAM | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GFY | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GFY | c.434C>A p.P145Q | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GFY | c.1298G>C p.R433P | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- GLYCTK | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- GOLGA8F | c.749C>G p.A250G (on ENST00000526619; = p.A456G on NM_001350920.2) | Missense Mutation (SNP) | VAF 40/455 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- GRID2 | c.1937C>A p.S646* | Nonsense Mutation (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2
- GRM4 | c.1593G>C p.K531N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSDMC | c.1495C>G p.L499V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSK3B | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GXYLT2 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GYPB | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.518); called by muse, varscan2
- GYS2 | c.2101T>C p.Y701H | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAND2 | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCLS1 | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 26/226 reads (12%) | called by muse, mutect2, varscan2
- HCN1 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 128/636 reads (20%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.974); called by muse, varscan2
- HCRTR2 | c.1329C>A p.N443K | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- HELZ | c.4643T>G p.L1548R | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); called by muse, mutect2
- HELZ2 | c.2251A>T p.S751C (on ENST00000467148 / NM_001037335.2; = p.S182C on NM_033405.3) | Missense Mutation (SNP) | VAF 53/356 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- HERC2 | c.10660A>C p.K3554Q | Missense Mutation (SNP) | VAF 115/342 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- HHIPL2 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HIF3A | c.307G>T p.E103* (on ENST00000377670 / NM_152795.4; = p.E101* on NM_152794.4) | Nonsense Mutation (SNP) | VAF 38/242 reads (16%) | called by muse, mutect2, varscan2
- HNF4A | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- HOXA13 | c.483G>C p.Q161H | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HOXD1 | c.711C>A p.S237R | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HPD | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 45/447 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HRH2 | c.1073A>T p.D358V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HS3ST4 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- IDE | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IFFO1 | c.1099G>A p.E367K (on ENST00000396840 / NM_001330324.2; = p.E370K on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- IFI30 | c.172A>C p.N58H | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- IFT52 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IGHM | c.1301-1G>C p.X434_splice | Splice Site (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- IL18RAP | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2
- IL1RL1 | c.970+8G>A | Splice Region (SNP) | VAF 25/171 reads (15%) | called by muse, mutect2
- IPO8 | c.905A>T p.Q302L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IQSEC3 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ITGAM | c.2653G>C p.D885H (on ENST00000648685 / NM_001145808.2; = p.D884H on NM_000632.4) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); called by muse, mutect2
- KANK2 | c.1186A>G p.T396A | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNAB1 | c.752A>G p.Y251C (on ENST00000490337 / NM_172160.3; = p.Y240C on NM_003471.3) | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNJ11 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- KCNK15 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- KCNK2 | c.548C>G p.P183R (on ENST00000444842 / NM_001017425.3; = p.P168R on NM_014217.4) | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIRREL2 | c.1807T>C p.Y603H | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL3 | c.570C>A p.S190R | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- KMT2E | c.1486A>C p.K496Q | Missense Mutation (SNP) | VAF 43/396 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- KMT2E | c.2337C>A p.Y779* | Nonsense Mutation (SNP) | VAF 71/310 reads (23%) | called by muse, mutect2, varscan2
- KNDC1 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KNSTRN | c.486C>G p.G162= | Splice Region (SNP) | VAF 85/193 reads (44%) | called by muse, mutect2, varscan2
- KRT12 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KRT73 | c.1156del p.D386Tfs*36 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, varscan2
- KRTAP10-12 | c.535T>A p.C179S | Missense Mutation (SNP) | VAF 179/641 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- KRTAP24-1 | c.646A>T p.T216S | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAMA3 | c.7366G>T p.G2456C (on ENST00000313654 / NM_198129.4; = p.G847C on NM_000227.6) | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB4 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- LARP1 | c.1943_1945delinsTAGT p.Q648Lfs*33 (on ENST00000518297 / NM_033551.3; = p.Q571Lfs*33 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 17/95 reads (18%) | called by pindel, varscan2*
- LGR5 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LIN9 | c.1393G>C p.E465Q (on ENST00000366808 / NM_001270410.2; = p.E410Q on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/295 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- LMBR1 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LOXHD1 | c.3907A>G p.T1303A | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- LRRC9 | c.2290C>A p.H764N | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- LRRK2 | c.1410T>A p.F470L | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LRRK2 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 22/224 reads (10%) | called by muse, mutect2, varscan2
- LUM | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- MACC1 | c.1353A>C p.E451D | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MAEA | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 35/357 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MAGED1 | c.1420A>G p.R474G | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MAP1A | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MARCHF6 | c.1275G>A p.W425* | Nonsense Mutation (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- MCF2L2 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- MDGA2 | c.2233A>T p.R745W (on ENST00000399232 / NM_001113498.2; = p.R447W on NM_182830.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- MED12L | c.2128C>G p.H710D | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MEFV | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MEGF8 | c.8464G>T p.G2822C (on ENST00000251268 / NM_001271938.2; = p.G2755C on NM_001410.3) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MKI67 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MNS1 | c.412dup p.A138Gfs*6 | Frame Shift Ins (INS) | VAF 43/283 reads (15%) | called by mutect2, pindel, varscan2
- MPL | c.1424G>A p.S475N | Missense Mutation (SNP) | VAF 107/354 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MRPL50 | c.31A>T p.R11* | Nonsense Mutation (SNP) | VAF 30/274 reads (11%) | called by muse, mutect2, varscan2
- MTCL1 | c.1704G>T p.K568N (on ENST00000306329 / NM_001378206.1; = p.K208N on NM_015210.4) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC17 | c.755A>C p.Q252P | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- MXRA5 | c.6884G>A p.G2295D | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MXRA5 | c.6883G>T p.G2295C | Missense Mutation (SNP) | VAF 38/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYCBP2 | c.5173G>C p.V1725L (on ENST00000357337; = p.V1763L on NM_015057.5) | Missense Mutation (SNP) | VAF 61/302 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- MYH10 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 35/425 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2
- MYH8 | c.1921A>T p.K641* | Nonsense Mutation (SNP) | VAF 198/455 reads (44%) | called by muse, mutect2, varscan2
- MYO1D | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MYO7B | c.3986A>T p.E1329V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2
- MYRIP | c.891C>G p.F297L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- MYT1L | c.2219G>C p.R740P | Missense Mutation (SNP) | VAF 60/322 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NARS2 | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 45/419 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEA | c.2263G>T p.A755S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NBPF12 | c.2074G>C p.E692Q | Missense Mutation (SNP) | VAF 53/624 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- NEB | c.7705G>C p.E2569Q | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- NEDD4 | c.872del p.G291Dfs*48 | Frame Shift Del (DEL) | VAF 45/124 reads (36%) | called by mutect2, pindel, varscan2
- NKX6-1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NPBWR1 | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR3C1 | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- NTNG1 | c.1391-2A>T p.X464_splice (on ENST00000370068 / NM_001113226.3; = p.X363_splice on NM_014917.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- NTRK3 | c.1006C>A p.L336M | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- NUDT3 | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 92/261 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUP188 | c.353G>C p.S118T | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- NXPE4 | c.1317C>A p.F439L (on ENST00000375478 / NM_001077639.2; = p.F155L on NM_017678.3) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- OR10P1 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 69/397 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- OR4C6 | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- OR56B1 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5B17 | c.74T>A p.L25H | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR5D14 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- OR6F1 | c.334T>A p.Y112N | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR9A4 | c.485T>A p.V162D | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OR9G4 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 57/364 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ORMDL3 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 30/240 reads (13%) | called by muse, mutect2, varscan2
- OSR1 | c.647A>T p.D216V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by mutect2, varscan2
- OVGP1 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- PARVA | c.354C>G p.D118E | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- PATL1 | c.1280A>C p.Y427S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDH1 | c.1499A>G p.N500S | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PCDH15 | c.1058T>G p.V353G | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PCDHA10 | c.1225G>C p.D409H | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PCDHB7 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PCNT | c.5336A>T p.Q1779L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- PCSK1N | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 67/490 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PDE1C | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.706); called by muse, mutect2
- PDE9A | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- PEG10 | c.151A>T p.T51S (on ENST00000482108 / NM_001040152.2; = p.T85S on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEG3 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 77/284 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PER1 | c.3616G>A p.G1206R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.728); called by muse, mutect2
- PFAS | c.1479G>C p.Q493H | Missense Mutation (SNP) | VAF 28/419 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PHLPP2 | c.770C>A p.S257* | Nonsense Mutation (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- PIEZO1 | c.800A>G p.Q267R | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PIGU | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 74/452 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PIK3C2B | c.2376C>G p.I792M | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PITPNM1 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIWIL1 | c.546T>A p.F182L | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKP1 | c.299del p.G100Dfs*97 | Frame Shift Del (DEL) | VAF 76/569 reads (13%) | called by mutect2, pindel, varscan2
- PLA2G3 | c.749A>T p.Q250L | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PLCH1 | c.3671C>G p.S1224* (on ENST00000340059 / NM_001130960.2; = p.S1216* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/266 reads (8%) | called by muse, mutect2
- PLXNB3 | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR2B | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2, varscan2
- POLR3A | c.1568T>G p.M523R | Missense Mutation (SNP) | VAF 53/444 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- POTEB3 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 44/542 reads (8%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.025); called by muse, mutect2
- POTEE | c.932T>C p.L311P | Missense Mutation (SNP) | VAF 32/661 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- POU5F1B | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PPM1E | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PPP1R21 | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R9A | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PPP2R3A | c.1346C>A p.A449E | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRAMEF10 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, varscan2
- PRAMEF10 | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, varscan2
- PRPF38B | c.650dup p.L217Ffs*14 | Frame Shift Ins (INS) | VAF 45/354 reads (13%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.7739G>T p.G2580V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PTGER4 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PTPRB | c.4646G>T p.G1549V | Missense Mutation (SNP) | VAF 49/385 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRN2 | c.1145A>T p.Q382L | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTPRO | c.1777G>T p.V593L | Missense Mutation (SNP) | VAF 51/312 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RALGAPB | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RALGDS | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- RBFOX1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RC3H2 | c.2714G>T p.W905L | Missense Mutation (SNP) | VAF 111/403 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- RELN | c.8050C>G p.R2684G | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RELN | c.7664G>T p.S2555I | Missense Mutation (SNP) | VAF 58/556 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); called by muse, mutect2
- RNASEL | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 56/382 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF103 | c.1011G>A p.M337I | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RNF148 | c.266T>C p.L89S | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RPL26 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SBF1 | c.2570-2A>T p.X857_splice | Splice Site (SNP) | VAF 29/161 reads (18%) | called by muse, mutect2, varscan2
- SCN7A | c.4243T>C p.S1415P | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SCN8A | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SEMG1 | c.943T>C p.Y315H | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SERPINB10 | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SETD1B | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- SEZ6 | c.2419G>T p.G807C | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SFMBT2 | c.2179A>G p.M727V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHPK | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- SIN3B | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SIPA1L1 | c.3472G>C p.D1158H | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- SLC22A24 | c.104T>C p.I35T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- SLC22A6 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC25A13 | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 84/452 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SLC2A2 | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 64/563 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC32A1 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SLC32A1 | c.1190C>A p.P397Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SLC35G5 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC39A4 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLITRK4 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- SLX4 | c.5239G>T p.V1747L | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SMARCA4 | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by mutect2, varscan2
- SMARCA4 | c.2907C>G p.H969Q | Missense Mutation (SNP) | VAF 63/327 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMG1 | c.2959C>G p.L987V | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMYD3 | c.190C>T p.Q64* (on ENST00000490107 / NM_001375962.1; = p.Q5* on NM_022743.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 86/420 reads (20%) | called by muse, mutect2, varscan2
- SNRNP48 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- SNX11 | c.205C>G p.Q69E | Missense Mutation (SNP) | VAF 73/561 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- SOX6 | c.1055C>T p.T352I | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- SP1 | c.555A>C p.Q185H (on ENST00000327443 / NM_138473.3; = p.Q178H on NM_003109.1) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SPOCK3 | c.403A>T p.I135L | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRCIN1 | c.697G>A p.E233K (on ENST00000621492; = p.E199K on NM_025248.3) | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2
- SRFBP1 | c.1263G>T p.Q421H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SRRM1 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 128/412 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- SSC5D | c.4595C>A p.A1532D | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- STIP1 | c.1063A>T p.I355L | Missense Mutation (SNP) | VAF 64/448 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- STK38L | c.939G>T p.M313I | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- STXBP1 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.382); called by muse, varscan2
- SUPT5H | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SV2A | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TAS2R14 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); called by muse, varscan2
- TAS2R5 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 87/344 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TBC1D30 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TCHHL1 | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 54/520 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- TCN1 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TDRD15 | c.2512del p.Q838Kfs*5 | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | called by mutect2, pindel, varscan2
- TECPR1 | c.3003G>T p.W1001C | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TECPR1 | c.3002G>T p.W1001L | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- TEK | c.3043T>C p.Y1015H | Missense Mutation (SNP) | VAF 79/419 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TERF2IP | c.968T>G p.I323S | Missense Mutation (SNP) | VAF 44/294 reads (15%) | called by muse, mutect2, varscan2
- TET3 | c.2709G>C p.K903N | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEX15 | c.2590A>G p.T864A (on ENST00000256246; = p.T1247A on NM_001350162.2) | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TGFBR3 | c.2513G>T p.G838V | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THAP2 | c.72-3_72delinsTTTT p.X24_splice | Splice Site (ONP) | VAF 4/39 reads (10%) | called by pindel, varscan2*
- THAP6 | c.154A>G p.I52V | Missense Mutation (SNP) | VAF 102/498 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THBS3 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 26/300 reads (9%) | called by muse, mutect2
- THSD7B | c.3329G>A p.C1110Y (on ENST00000272643; = p.C1108Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIMD4 | c.967T>A p.L323M | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TMED3 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM260 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMOD2 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMOD2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 51/490 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- TNFRSF13C | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFRSF13C | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNFRSF4 | c.649G>C p.A217P | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TNRC6A | c.2098C>A p.Q700K | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- TNS3 | c.4145C>T p.A1382V | Missense Mutation (SNP) | VAF 48/448 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOX | c.632A>T p.K211M | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAF4 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2
- TRAPPC1 | c.215A>T p.H72L | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRBV3-1 | c.158G>C p.W53S | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM64C | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TRIP11 | c.3276G>T p.Q1092H | Missense Mutation (SNP) | VAF 277/562 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- TRMT2A | c.739del p.V247Lfs*43 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- TRPM7 | c.3559G>T p.D1187Y | Missense Mutation (SNP) | VAF 101/276 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPV5 | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTYH1 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TUBA3C | c.146T>A p.F49Y | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- U2SURP | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- UBAP2L | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE3D | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBN1 | c.1153A>T p.T385S | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.134); called by muse, mutect2
- UBOX5 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UHRF1BP1 | c.3475C>T p.Q1159* | Nonsense Mutation (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- ULK4 | c.2781_2781+3del p.X927_splice | Splice Site (DEL) | VAF 13/97 reads (13%) | called by mutect2, pindel, varscan2
- UPK3B | c.785C>A p.P262H (on ENST00000257632; = p.P234T on NM_001347684.2) | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- URB2 | c.2327A>T p.Q776L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- USF3 | c.3413G>C p.R1138T | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- USP10 | c.1876C>A p.Q626K | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USPL1 | c.1255A>G p.M419V | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- VIM | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- VPS16 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 32/394 reads (8%) | called by muse, mutect2
- VPS35L | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- VSTM4 | c.694A>T p.T232S | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- VSX2 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- VWDE | c.2485A>T p.K829* | Nonsense Mutation (SNP) | VAF 52/395 reads (13%) | called by muse, mutect2, varscan2
- WDR72 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- WEE2 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 58/430 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- XAB2 | c.1876G>C p.A626P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XPR1 | c.304A>C p.T102P | Missense Mutation (SNP) | VAF 47/401 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRN1 | c.2765G>A p.G922E | Missense Mutation (SNP) | VAF 29/356 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- ZBBX | c.1498A>T p.T500S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZBTB42 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- ZFHX3 | c.891T>G p.F297L | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZFHX4 | c.8848G>T p.D2950Y | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFHX4 | c.9688G>T p.G3230C | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ZGRF1 | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZGRF1 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZMYM2 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZNF189 | c.265A>T p.S89C | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ZNF202 | c.1435A>T p.K479* | Nonsense Mutation (SNP) | VAF 44/146 reads (30%) | called by muse, mutect2, varscan2
- ZNF287 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF398 | c.1471G>A p.D491N (on ENST00000475153 / NM_170686.3; = p.D320N on NM_020781.4) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- ZNF541 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF541 | c.2568C>A p.H856Q | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- ZNF582 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF638 | c.5816G>T p.G1939V | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- ZNF736 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZNF746 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); called by mutect2, varscan2
- ZNF775 | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 122/492 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNFX1 | c.3208A>G p.N1070D | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- A2M | c.2925G>A p.Q975= | Silent (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- ABCB11 | c.585G>A p.V195= | Silent (SNP) | VAF 32/319 reads (10%) | catalogued as rs11568365; called by muse, mutect2, varscan2
- ADAMTS16 | c.12C>A p.R4= | Silent (SNP) | VAF 29/308 reads (9%) | catalogued as rs1159877030; called by muse, mutect2, varscan2
- AKR1B10 | c.51C>A p.G17= | Silent (SNP) | VAF 24/240 reads (10%) | called by mutect2, varscan2
- ALDH2 | c.303G>A p.R101= | Silent (SNP) | VAF 28/198 reads (14%) | catalogued as rs768692057; called by muse, mutect2, varscan2
- ANKMY1 | c.21G>T p.G7= | Silent (SNP) | VAF 39/232 reads (17%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1917A>G p.L639= | Silent (SNP) | VAF 100/260 reads (38%) | called by muse, mutect2, varscan2
- ANOS1 | c.1155G>A p.L385= | Silent (SNP) | VAF 69/390 reads (18%) | catalogued as rs1394602627; called by muse, mutect2, varscan2
- APPL1 | c.1605T>C p.H535= | Silent (SNP) | VAF 101/325 reads (31%) | called by muse, mutect2, varscan2
- ASF1B | c.45G>A p.P15= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- ASXL3 | c.4797T>C p.N1599= | Silent (SNP) | VAF 46/304 reads (15%) | catalogued as rs1468244014; called by muse, mutect2, varscan2
- ASXL3 | c.5073G>T p.L1691= | Silent (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- ASXL3 | c.6390A>T p.P2130= | Silent (SNP) | VAF 30/137 reads (22%) | called by muse, mutect2, varscan2
- AVEN | c.933G>A p.L311= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- AXL | c.1002G>C p.L334= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV56565402; called by muse, varscan2
- BARD1 | c.1251G>A p.L417= | Silent (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2
- BCAS4 | c.561C>A p.S187= | Silent (SNP) | VAF 16/165 reads (10%) | called by mutect2, varscan2
- BCL7B | c.361C>T p.L121= | Silent (SNP) | VAF 61/398 reads (15%) | called by muse, mutect2, varscan2
- BSN | c.4743C>G p.L1581= | Silent (SNP) | VAF 10/82 reads (12%) | called by mutect2, varscan2
- BTNL9 | c.75C>T p.H25= | Silent (SNP) | VAF 40/396 reads (10%) | called by muse, mutect2, varscan2
- C11orf94 | c.225C>A p.L75= | Silent (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- CA4 | c.909G>T p.L303= | Silent (SNP) | VAF 37/235 reads (16%) | called by muse, mutect2, varscan2
- CACNA1E | c.3222C>T p.I1074= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- CAPN15 | c.1509C>A p.P503= | Silent (SNP) | VAF 63/435 reads (14%) | called by muse, mutect2, varscan2
- CCDC136 | c.1035C>G p.L345= | Silent (SNP) | VAF 32/514 reads (6%) | catalogued as COSV52798001; called by muse, mutect2
- CCDC166 | c.1218C>G p.L406= | Silent (SNP) | VAF 24/278 reads (9%) | called by muse, mutect2
- CDH11 | c.2169G>T p.T723= | Silent (SNP) | VAF 40/339 reads (12%) | called by muse, mutect2, varscan2
- CDH18 | c.834T>C p.P278= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs766602562; called by mutect2, varscan2
- CDH2 | c.1368G>A p.R456= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- CDH8 | c.1494C>G p.S498= | Silent (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- CDHR5 | c.2400C>G p.L800= (on ENST00000358353 / NM_001171968.2; = p.L806= on NM_021924.5) | Silent (SNP) | VAF 65/472 reads (14%) | called by muse, mutect2, varscan2
- CEMIP | c.1455G>A p.V485= | Silent (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- CHD7 | c.489G>A p.Q163= | Silent (SNP) | VAF 45/232 reads (19%) | called by muse, mutect2, varscan2
- CIITA | c.3141C>G p.L1047= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- CIT | c.2436C>T p.L812= | Silent (SNP) | VAF 43/305 reads (14%) | catalogued as COSV99951017; called by muse, mutect2, varscan2
- CLDN22 | c.495C>A p.A165= | Silent (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- CLSPN | c.3315T>C p.T1105= | Silent (SNP) | VAF 69/219 reads (32%) | catalogued as rs1262088643; called by muse, mutect2, varscan2
- CNBD1 | c.963T>A p.P321= | Silent (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- CNKSR1 | c.1878A>G p.L626= (on ENST00000374253 / NM_001297647.2; = p.L619= on NM_006314.3) | Silent (SNP) | VAF 56/173 reads (32%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2598A>G p.P866= | Silent (SNP) | VAF 123/490 reads (25%) | called by muse, mutect2, varscan2
- COL21A1 | c.840A>G p.S280= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs577206382; called by mutect2, varscan2
- CORIN | c.180C>T p.L60= | Silent (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- CRTC1 | c.792C>A p.P264= | Silent (SNP) | VAF 38/318 reads (12%) | called by muse, mutect2, varscan2
- CSPG4 | c.2973G>A p.Q991= | Silent (SNP) | VAF 64/161 reads (40%) | called by muse, mutect2, varscan2
- CTSG | c.15G>T p.L5= | Silent (SNP) | VAF 35/244 reads (14%) | called by muse, mutect2, varscan2
- CYP26C1 | c.1182C>T p.F394= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99605969; called by muse, mutect2, varscan2
- DCC | c.2319T>G p.R773= | Silent (SNP) | VAF 63/224 reads (28%) | called by muse, varscan2
- DIPK2B | c.624G>C p.L208= | Silent (SNP) | VAF 30/181 reads (17%) | called by muse, mutect2, varscan2
- DNAH9 | c.7377T>A p.R2459= | Silent (SNP) | VAF 53/320 reads (17%) | called by muse, mutect2, varscan2
- DNAH9 | c.10518T>A p.A3506= | Silent (SNP) | VAF 56/384 reads (15%) | called by muse, mutect2, varscan2
- DNAJB13 | c.768G>T p.L256= | Silent (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- DOP1B | c.3615C>T p.L1205= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs200377583, COSV101214931, COSV67693871; called by muse, mutect2, varscan2
- DUSP11 | c.954A>T p.P318= | Silent (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- DUSP7 | c.1212G>T p.T404= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2
- DYRK4 | c.774C>T p.H258= | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as rs755905479; called by muse, mutect2, varscan2
- E2F7 | c.2295G>C p.P765= | Silent (SNP) | VAF 66/500 reads (13%) | catalogued as COSV59738570; called by muse, mutect2, varscan2
- EDC4 | c.900C>G p.L300= | Silent (SNP) | VAF 41/201 reads (20%) | called by muse, mutect2, varscan2
- ELP5 | c.903T>A p.A301= | Silent (SNP) | VAF 62/380 reads (16%) | called by muse, mutect2, varscan2
- ENAH | c.96C>T p.F32= | Silent (SNP) | VAF 46/363 reads (13%) | called by muse, mutect2, varscan2
- ENOX2 | c.1653A>T p.G551= (on ENST00000338144 / NM_001382520.1; = p.G522= on NM_006375.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2
- ENPP2 | c.849G>A p.E283= | Silent (SNP) | VAF 28/201 reads (14%) | called by muse, mutect2, varscan2
- EPG5 | c.6819C>G p.V2273= | Silent (SNP) | VAF 55/294 reads (19%) | called by muse, mutect2, varscan2
- EPHB6 | c.795T>A p.A265= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- ETAA1 | c.819A>G p.P273= | Silent (SNP) | VAF 36/281 reads (13%) | catalogued as rs1257921394; called by muse, mutect2, varscan2
- EXOC4 | c.453C>T p.L151= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2
- FAM189A1 | c.288C>T p.F96= | Silent (SNP) | VAF 80/190 reads (42%) | called by muse, varscan2
- FAM193A | c.3147G>A p.L1049= | Silent (SNP) | VAF 72/301 reads (24%) | catalogued as COSV61191745; called by muse, mutect2, varscan2
- FAM47C | c.1893C>T p.R631= | Silent (SNP) | VAF 69/386 reads (18%) | called by muse, varscan2
- FAM78B | c.510G>T p.T170= | Silent (SNP) | VAF 12/85 reads (14%) | called by mutect2, varscan2
- FAM86B1 | c.156G>A p.Q52= | Silent (SNP) | VAF 52/569 reads (9%) | called by muse, mutect2, varscan2
- FYB2 | c.408C>T p.F136= | Silent (SNP) | VAF 31/209 reads (15%) | called by muse, mutect2, varscan2
- GABRA3 | c.543T>C p.Y181= | Silent (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- GGCX | c.21C>A p.S7= | Silent (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- GGNBP2 | c.687C>T p.I229= | Silent (SNP) | VAF 51/359 reads (14%) | called by muse, mutect2, varscan2
- GGPS1 | c.486C>T p.L162= | Silent (SNP) | VAF 36/310 reads (12%) | catalogued as rs988281633; called by muse, mutect2, varscan2
- GK3P | c.204A>T p.I68= | Silent (SNP) | VAF 49/311 reads (16%) | called by muse, mutect2, varscan2
- GLI4 | c.1005C>G p.R335= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2, varscan2
- GPT | c.729C>A p.G243= | Silent (SNP) | VAF 20/189 reads (11%) | called by muse, varscan2
- GRIA3 | c.93C>A p.P31= | Silent (SNP) | VAF 30/376 reads (8%) | called by muse, mutect2
- GRIN2B | c.951C>A p.P317= | Silent (SNP) | VAF 32/234 reads (14%) | called by muse, mutect2, varscan2
- GRM3 | c.756C>T p.I252= | Silent (SNP) | VAF 52/454 reads (11%) | called by muse, mutect2, varscan2
- GRM8 | c.2370C>A p.T790= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV58835202, COSV58864743; called by muse, mutect2
- GRP | c.264A>C p.I88= | Silent (SNP) | VAF 77/436 reads (18%) | called by muse, mutect2, varscan2
- HDDC3 | c.390G>A p.L130= | Silent (SNP) | VAF 43/110 reads (39%) | called by muse, mutect2, varscan2
- HGF | c.9G>T p.V3= | Silent (SNP) | VAF 56/493 reads (11%) | called by muse, mutect2, varscan2
- HIC2 | c.1578G>A p.T526= | Silent (SNP) | VAF 83/303 reads (27%) | catalogued as rs149833696; called by muse, mutect2, varscan2
- HOXD3 | c.1038C>T p.F346= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as rs1240718044, COSV50882401; called by muse, mutect2, varscan2
- HTRA1 | c.933C>T p.N311= | Silent (SNP) | VAF 40/298 reads (13%) | called by muse, mutect2, varscan2
- HYOU1 | c.519G>C p.V173= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs782170524; called by muse, mutect2, varscan2
- IFFO1 | c.1098G>A p.R366= (on ENST00000396840 / NM_001330324.2; = p.R369= on NM_080730.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/152 reads (16%) | called by muse, mutect2, varscan2
- IGHV3-48 | c.144C>T p.F48= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as rs782375734; called by muse, varscan2
- IL7R | c.1227G>T p.G409= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57408788; called by mutect2, varscan2
- IPO8 | c.1335G>T p.L445= | Silent (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- IRS4 | c.1611C>A p.G537= | Silent (SNP) | VAF 40/502 reads (8%) | called by muse, mutect2
- ITGA10 | c.3012G>A p.L1004= | Silent (SNP) | VAF 24/228 reads (11%) | called by muse, mutect2
- ITGA6 | c.2922G>C p.V974= (on ENST00000442250; = p.V935= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/390 reads (12%) | called by muse, mutect2, varscan2
- ITGB8 | c.1242A>T p.P414= | Silent (SNP) | VAF 30/451 reads (7%) | called by muse, mutect2
- ITPR2 | c.2547C>G p.P849= | Silent (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- KBTBD11 | c.1092G>A p.A364= | Silent (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- KIF23 | c.2436A>G p.S812= (on ENST00000260363; = p.S708= on NM_004856.7) | Silent (SNP) | VAF 100/269 reads (37%) | called by muse, mutect2, varscan2
- KIF2B | c.798C>T p.F266= | Silent (SNP) | VAF 47/237 reads (20%) | catalogued as rs780981852, COSV52130774; called by muse, mutect2, varscan2
- KIF9 | c.813G>C p.S271= | Silent (SNP) | VAF 57/195 reads (29%) | called by muse, mutect2, varscan2
- KLHL13 | c.600A>T p.G200= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, varscan2
- LCE2C | c.253C>A p.R85= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as COSV64228433; called by muse, mutect2, varscan2
- LCP2 | c.705A>T p.I235= | Silent (SNP) | VAF 34/414 reads (8%) | called by muse, mutect2
- LENG8 | c.2184C>T p.L728= | Silent (SNP) | VAF 25/208 reads (12%) | catalogued as rs777123061; called by muse, mutect2, varscan2
- LPCAT1 | c.81G>T p.P27= | Silent (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- LRFN5 | c.1617A>G p.A539= | Silent (SNP) | VAF 41/307 reads (13%) | called by muse, mutect2, varscan2
- LRIT2 | c.585G>T p.V195= | Silent (SNP) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- LRP1B | c.13383A>T p.V4461= | Silent (SNP) | VAF 28/217 reads (13%) | called by muse, mutect2, varscan2
- LRRN3 | c.924G>T p.L308= | Silent (SNP) | VAF 36/241 reads (15%) | called by muse, mutect2, varscan2
- LY9 | c.258T>A p.A86= | Silent (SNP) | VAF 94/536 reads (18%) | called by muse, mutect2, varscan2
- MAGEB6B | c.1131C>A p.A377= | Silent (SNP) | VAF 30/181 reads (17%) | catalogued as rs962508694; called by muse, mutect2, varscan2
- MAP1A | c.3774C>A p.P1258= | Silent (SNP) | VAF 96/250 reads (38%) | called by muse, mutect2, varscan2
244 further variants in this file (0 protein-altering or splice-affecting, 118 silent, 126 other) are not listed here.
